Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96B, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96B-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Thymoma, type B1
malignant 8583/3
Site Thymus C37.9
JW 4/7/14

Pathology Report-Summary:

Material:

tumor: 16.0 x 7.0 x 8.0 cm

focal infiltration into capsule, but capsule is intact

Diagnosis:

Type B1-Thymoma

pT2, pNx, pMx

Masaoka: II

Immunohistochemistry

epithelial cells positive for: CK5/6, AE1/3
strong membrane staining for EGFR

epithelial cells negative for: CD5, CD117

CD1a-, CD99-positive immature T-lymphocytes

Source: NCI Genomic Data Commons file b7b5aaca-a884-4cb0-902c-47994795c274 (TCGA-ZB-A96B.6EC60C7E-EC20-4A58-A3A2-26A27E4EF1A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).